Somatic mutation profile of tumor specimen C3N-00953-02 (aliquot CPT0065430009) from CPTAC case C3N-00953, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 41.4 years (15,137 days).
Specimen C3N-00953-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca0d3c11-c08b-46f6-90aa-50faff089a68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00953-31 (Blood Derived Normal), aliquot CPT0070680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fdc2513-9bc1-4dfa-bfa1-fe9f34a64093

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Frame Shift Del 5, Intron 4, Frame Shift Ins 2, Nonsense Mutation 2, 3'UTR 2, 5'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM133A | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs1476222624; called by muse, mutect2, varscan2
- FGFR3 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs774934127, COSV99601289; called by muse, mutect2, varscan2
- HERC1 | c.13366A>G p.M4456V | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs773560667; called by muse, mutect2, varscan2
- PCDHA11 | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 98/649 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV56484777; called by muse, mutect2, varscan2
- PCDHGB1 | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 61/488 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs926788481; called by muse, mutect2, varscan2
- PRAG1 | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV58164802; called by muse, mutect2
- PRAMEF8 | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 112/1313 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1347550555; called by muse, mutect2
- PRKCG | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 144/686 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54730150; called by muse, mutect2, varscan2
- RCN1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs377179238; called by muse, mutect2, varscan2
- RTF1 | c.602A>C p.E201A | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101047824, COSV67478521; called by muse, mutect2, varscan2
- VHL | c.349dup p.W117Lfs*15 | Frame Shift Ins (INS) | VAF 62/346 reads (18%) | catalogued as COSV56547585; called by mutect2, pindel, varscan2
- ADAMTS1 | c.2566T>A p.S856T | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- BAP1 | c.1009A>T p.K337* | Nonsense Mutation (SNP) | VAF 42/173 reads (24%) | called by muse, mutect2, varscan2
- DNAJC14 | c.841del p.S281Afs*18 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | called by pindel, varscan2
- DPH2 | c.923del p.Q308Rfs*32 | Frame Shift Del (DEL) | VAF 22/149 reads (15%) | called by mutect2, pindel, varscan2
- EFHB | c.997-1_997insA p.A333Sfs*18 | Frame Shift Ins (INS) | VAF 7/56 reads (13%) | called by mutect2, pindel
- GOLGB1 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- MAGEA12 | c.38A>T p.E13V | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MAGEE2 | c.599G>T p.W200L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- MKLN1 | c.862T>A p.F288I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MMS19 | c.928T>G p.F310V | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- MOG | c.728T>A p.L243Q | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- OCEL1 | c.240_241del p.P82Afs*35 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- PCDH15 | c.99A>T p.K33N | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RNF11 | c.215A>C p.Q72P | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, varscan2
- SMG1 | c.2342G>T p.S781I | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- TIMM23B | c.530del p.L177Wfs*28 | Frame Shift Del (DEL) | VAF 32/219 reads (15%) | called by mutect2, pindel, varscan2
- UNG | c.733A>G p.N245D (on ENST00000242576 / NM_080911.3; = p.N236D on NM_003362.4) | Missense Mutation (SNP) | VAF 65/431 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFY | c.174T>A p.D58E | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF600 | c.393_400del p.Q132Yfs*3 | Frame Shift Del (DEL) | VAF 18/109 reads (17%) | called by mutect2, pindel, varscan2
- DLG4 | c.1794C>T p.F598= (on ENST00000399506 / NM_001321075.3; = p.F641= on NM_001365.4) | Silent (SNP) | VAF 34/188 reads (18%) | called by muse, mutect2, varscan2
- EGFL8 | c.138G>A p.P46= | Silent (SNP) | VAF 22/204 reads (11%) | catalogued as rs575900965; called by muse, mutect2, varscan2
- MIGA2 | c.264C>T p.P88= | Silent (SNP) | VAF 60/257 reads (23%) | catalogued as rs538683313; called by muse, mutect2, varscan2
- PCDHB16 | c.1596C>T p.G532= | Silent (SNP) | VAF 64/633 reads (10%) | catalogued as rs782139928, COSV53370404; called by muse, mutect2, varscan2
- RCOR2 | c.192C>T p.P64= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as rs754428923; called by muse, mutect2, varscan2
- RXFP3 | c.714G>A p.T238= | Silent (SNP) | VAF 32/214 reads (15%) | catalogued as rs547132118, COSV57508081; called by muse, mutect2, varscan2
- SMG1 | c.2343C>T p.S781= | Silent (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- COL18A1 | c.3928+690G>C | Intron (SNP) | VAF 70/426 reads (16%) | catalogued as rs774218242, COSV60587663; called by mutect2, varscan2
- DCLRE1CP1 | n.315G>A | RNA (SNP) | VAF 67/566 reads (12%) | called by muse, mutect2, varscan2
- DNAH8 | chr6:38723060 T>A | 5'Flank (SNP) | VAF 11/303 reads (4%) | called by muse, mutect2
- FANCC | c.*26C>T | 3'UTR (SNP) | VAF 30/241 reads (12%) | catalogued as rs770935196; called by muse, mutect2, varscan2
- MALRD1 | c.5030-2387G>T | Intron (SNP) | VAF 21/149 reads (14%) | catalogued as rs1248619060; called by muse, mutect2, varscan2
- MED25 | c.2147-25C>T | Intron (SNP) | VAF 35/174 reads (20%) | catalogued as rs761720007; called by muse, mutect2, varscan2
- PTBP3 | c.-15G>T | 5'UTR (SNP) | VAF 39/152 reads (26%) | called by muse, mutect2, varscan2
- SPINK5 | c.2740-193T>C | Intron (SNP) | VAF 39/268 reads (15%) | catalogued as rs190012161; called by muse, mutect2, varscan2
- ZSWIM8 | c.*208G>C | 3'UTR (SNP) | VAF 42/204 reads (21%) | called by muse, mutect2, varscan2
